Somatic mutation profile of tumor specimen 0DFXGX from CCDI case PBBSPF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.4 years (878 days).
Specimen 0DFXGX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9266c1ab-1006-4a7c-9ef8-09867af81a44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFXF1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11b0e185-da7b-4513-8e9a-8497f3cc370a

The open-access MAF lists 7 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 3, Silent 2, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TONSL | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 258/1417 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.384); catalogued as rs765471510, COSV68047977; called by muse, mutect2, varscan2
- NLRC5 | c.2538G>A p.T846= | Silent (SNP) | VAF 288/1279 reads (23%) | catalogued as rs749550111, COSV99346514, COSV99347524; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPPL2C | c.1611C>T p.L537= | Silent (SNP) | VAF 200/1062 reads (19%) | catalogued as rs769108725; called by muse, varscan2
- MAN2B2 | c.*83C>T | 3'UTR (SNP) | VAF 22/225 reads (10%) | catalogued as rs959889675, COSV53452792; called by muse, mutect2
- PLAA | c.*17C>T | 3'UTR (SNP) | VAF 308/1757 reads (18%) | catalogued as rs373253466; called by muse, mutect2, varscan2
- SLC4A2 | c.52-1070C>T | Intron (SNP) | VAF 115/582 reads (20%) | catalogued as rs1172533502; called by muse, mutect2, varscan2
- SLC9A1 | c.*79C>T | 3'UTR (SNP) | VAF 45/132 reads (34%) | called by muse, mutect2, varscan2
